TARGET case TARGET-30-PAPTLA — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf89ba58-61e9-5f6c-b380-cae4f1bc7d4b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Dead; Days to death: 2,531 days (6.9 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 3.0 years (1,089 days); Year of diagnosis: 2006; Days to last follow up: 2,531 days (6.9 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 10.
   Treatment given: Protocol identifier: ADVL0911.
   Treatment given: Protocol identifier: ANBL0421.
   Treatment given: Protocol identifier: ADVL1111.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ADVL1011.

Follow-up (2 entries)
- Days to follow up: 645 days (1.8 years); Days to first event: 645 days (1.8 years); First event: Event.
- Days to follow up: 2,531 days (6.9 years); Year of follow up: 2013.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPTLA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPTLA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 2531
- Protocol: ANBL0032, ANBL0421, ADVL0911, ADVL1011, ADVL1111
- Ploidy: Hyperdiploid (DI>1)
- Histology: Unfavorable
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor v/s Stroma: 10/90
